Somatic mutation profile of tumor specimen TARGET-40-NAAWEW-01A (aliquot TARGET-40-NAAWEW-01A-01D) from TARGET case TARGET-40-NAAWEW, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 18.0 years (6,570 days).
Specimen TARGET-40-NAAWEW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfb90dd7-79ed-4781-86dd-df97a688f3d4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWEW-10A (Blood Derived Normal), aliquot TARGET-40-NAAWEW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4219fd25-16fd-46c2-8528-7518203a752e

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA2 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV63565176, COSV63573771; called by muse, mutect2, varscan2
- KCNH8 | c.2981C>G p.S994* | Nonsense Mutation (SNP) | VAF 139/204 reads (68%) | catalogued as COSV60464527; called by muse, mutect2, varscan2
- TTN | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 45/137 reads (33%) | PolyPhen benign (0); catalogued as rs1305775594, COSV60234003; called by muse, mutect2, varscan2
- HIVEP2 | c.4269G>C p.L1423F | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LZTR1 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SPATA6 | c.1343A>C p.N448T | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RBM47 | c.258G>A p.E86= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs754813778; called by muse, mutect2, varscan2
- ZFHX3 | c.3996C>T p.I1332= | Silent (SNP) | VAF 12/34 reads (35%) | called by mutect2, varscan2
